Somatic mutation profile of tumor specimen HTMCP-03-06-02384-01A (aliquot HTMCP-03-06-02384-01A-01D-10409) from CGCI case HTMCP-03-06-02384, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Small cell carcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIA2; Tumor grade: G3.
Specimen HTMCP-03-06-02384-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf488177-bc19-48af-aebb-e835702ca6c8.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02384-10A (Blood Derived Normal), aliquot HTMCP-03-06-02384-10A-01D-10409; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/679f2778-ac83-42d8-bcea-e84816e3c413

The open-access MAF lists 82 somatic variants for this specimen: 59 protein-altering or splice-affecting, 16 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 53, Silent 16, Intron 6, Nonsense Mutation 4, Splice Site 1, 5'Flank 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NFE2L2 | c.70T>C p.W24R | Missense Mutation (SNP) | VAF 67/149 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1328994103, COSV67960091, COSV67960815, COSV67963035; called by muse, mutect2, varscan2
- ATP2C2 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 46/72 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); catalogued as rs750932659; called by muse, mutect2, varscan2
- CDH23 | c.3925G>A p.E1309K | Missense Mutation (SNP) | VAF 57/101 reads (56%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as rs111033468, COSV56478126; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CEMIP | c.698C>T p.S233F | Missense Mutation (SNP) | VAF 89/200 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV54997115; called by muse, mutect2, varscan2
- COL22A1 | c.2966C>T p.P989L | Missense Mutation (SNP) | VAF 10/47 reads (21%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.842); catalogued as rs370576971; called by muse, mutect2, varscan2
- CUBN | c.5444C>A p.S1815Y | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.83); catalogued as rs1194699470, COSV64720056; called by muse, mutect2, varscan2
- CUL7 | c.2947C>T p.R983C | Missense Mutation (SNP) | VAF 48/93 reads (52%) | SIFT tolerated (0.19); PolyPhen benign (0.089); catalogued as rs147713438; called by muse, mutect2, varscan2
- DCC | c.3113T>A p.L1038H | Missense Mutation (SNP) | VAF 33/78 reads (42%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV59118539; called by muse, mutect2, varscan2
- EP300 | c.2962G>T p.E988* | Nonsense Mutation (SNP) | VAF 50/110 reads (45%) | catalogued as COSV99608051; called by muse, varscan2
- ERC2 | c.2854G>A p.E952K | Missense Mutation (SNP) | VAF 21/23 reads (91%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs1174595991; called by muse, mutect2, varscan2
- FAM135B | c.3259G>T p.E1087* | Nonsense Mutation (SNP) | VAF 18/50 reads (36%) | catalogued as COSV52737945; called by mutect2, varscan2
- FH | c.260G>A p.R87H | Missense Mutation (SNP) | VAF 50/287 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as rs200007371, COSV63818757; called by muse, mutect2, varscan2
- HAUS6 | c.154G>T p.D52Y | Missense Mutation (SNP) | VAF 238/488 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs371815503; called by muse, mutect2, varscan2
- LRRC37A3 | c.3847G>C p.E1283Q | Missense Mutation (SNP) | VAF 57/116 reads (49%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.932); catalogued as COSV58534225; called by muse, mutect2, varscan2
- MS4A14 | c.298G>A p.D100N | Missense Mutation (SNP) | VAF 29/46 reads (63%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs768900672, COSV55732833, COSV55733252; called by muse, mutect2, varscan2
- NLRP4 | c.2629G>A p.G877R | Missense Mutation (SNP) | VAF 55/194 reads (28%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.592); catalogued as rs772913904, COSV56718246; called by muse, mutect2, varscan2
- PRPF3 | c.1821G>C p.Q607H | Missense Mutation (SNP) | VAF 37/168 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.012); catalogued as COSV61394867; called by muse, mutect2, varscan2
- PTEN | c.44G>C p.R15T | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.247); catalogued as rs398123324, COSV100910708, COSV64297317, COSV64299553; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RAB3GAP2 | c.3088G>A p.E1030K | Missense Mutation (SNP) | VAF 51/240 reads (21%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.605); catalogued as rs770740537; called by muse, mutect2, varscan2
- RANBP6 | c.247G>C p.E83Q | Missense Mutation (SNP) | VAF 1928/2046 reads (94%) | SIFT tolerated (0.37); PolyPhen benign (0.01); catalogued as rs373190234; called by muse, mutect2, varscan2
- SEMA4F | c.1399C>T p.R467W | Missense Mutation (SNP) | VAF 74/202 reads (37%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.625); catalogued as rs774544086, COSV100335630; called by muse, mutect2, varscan2
- SORCS3 | c.1781C>A p.S594Y | Missense Mutation (SNP) | VAF 36/125 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV63809478; called by muse, mutect2, varscan2
- TIE1 | c.1441C>T p.R481C | Missense Mutation (SNP) | VAF 14/30 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.643); catalogued as rs139244400; called by muse, mutect2, varscan2
- TRHDE | c.2212C>A p.P738T | Missense Mutation (SNP) | VAF 22/60 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.069); catalogued as COSV53831780; called by muse, mutect2, varscan2
- TTI1 | c.2419G>A p.E807K | Missense Mutation (SNP) | VAF 140/324 reads (43%) | SIFT tolerated (0.22); PolyPhen benign (0.031); catalogued as COSV65063971; called by muse, mutect2, varscan2
- TTN | c.78756C>A p.S26252R (on ENST00000591111; = p.S18828R on NM_003319.4) | Missense Mutation (SNP) | VAF 77/382 reads (20%) | PolyPhen probably damaging (1); catalogued as rs761618267; called by muse, mutect2, varscan2
- TUT1 | c.1814C>G p.S605C | Missense Mutation (SNP) | VAF 21/71 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.018); catalogued as COSV53469257, COSV53471822; called by muse, mutect2, varscan2
- UNC80 | c.7278G>C p.Q2426H | Missense Mutation (SNP) | VAF 38/85 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs1292128559; called by muse, mutect2, varscan2
- WDR81 | c.4468G>A p.V1490M (on ENST00000409644 / NM_001163809.2; = p.V439M on NM_152348.4) | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.286); catalogued as rs779448914; called by muse, mutect2, varscan2
- ACLY | c.2673G>C p.E891D | Missense Mutation (SNP) | VAF 33/99 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AMBRA1 | c.2641A>G p.N881D (on ENST00000458649 / NM_001367468.1; = p.N791D on NM_017749.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen probably damaging (0.98); called by muse, mutect2
- ANK2 | c.1882-1G>A p.X628_splice | Splice Site (SNP) | VAF 91/107 reads (85%) | called by muse, mutect2, varscan2
- ATP11B | c.2131G>A p.E711K | Missense Mutation (SNP) | VAF 67/236 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNA1C | c.530_531del p.K177Sfs*32 | Frame Shift Del (DEL) | VAF 14/129 reads (11%) | called by mutect2, pindel, varscan2
- CFHR5 | c.299C>T p.S100L | Missense Mutation (SNP) | VAF 46/190 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.261); called by muse, mutect2, varscan2
- CPT1A | c.2054C>G p.S685* | Nonsense Mutation (SNP) | VAF 19/83 reads (23%) | called by muse, mutect2, varscan2
- EIF4G1 | c.4208G>A p.W1403* (on ENST00000346169 / NM_198241.3; = p.W1208* on NM_004953.5) | Nonsense Mutation (SNP) | VAF 24/88 reads (27%) | called by muse, mutect2, varscan2
- EP300 | c.2881G>C p.E961Q | Missense Mutation (SNP) | VAF 56/114 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.193); called by muse, varscan2
- HEXD | c.27G>A p.M9I | Missense Mutation (SNP) | VAF 47/101 reads (47%) | SIFT deleterious (0); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- IKZF1 | c.961T>A p.Y321N | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KIF26B | c.3713A>C p.D1238A | Missense Mutation (SNP) | VAF 30/246 reads (12%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- LRRC37A3 | c.4630G>C p.D1544H | Missense Mutation (SNP) | VAF 64/128 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.753); called by muse, mutect2, varscan2
- MARF1 | c.3922G>A p.E1308K | Missense Mutation (SNP) | VAF 63/104 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- MYH13 | c.2911G>C p.E971Q | Missense Mutation (SNP) | VAF 71/90 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- NLGN1 | c.1870T>C p.S624P | Missense Mutation (SNP) | VAF 175/579 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OBSCN | c.22850C>T p.S7617F | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- PDZD2 | c.4053A>T p.R1351S | Missense Mutation (SNP) | VAF 21/59 reads (36%) | SIFT tolerated (0.59); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- POM121 | c.323C>T p.S108L | Missense Mutation (SNP) | VAF 10/17 reads (59%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.572); called by muse, mutect2, varscan2
- PSD | c.1087G>A p.V363M | Missense Mutation (SNP) | VAF 27/47 reads (57%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.735); called by muse, mutect2, varscan2
- RANBP6 | c.790G>A p.E264K | Missense Mutation (SNP) | VAF 1975/2096 reads (94%) | SIFT tolerated (0.12); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- SCN8A | c.4744A>C p.T1582P | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SEMA5A | c.847G>A p.E283K | Missense Mutation (SNP) | VAF 63/171 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- SPAG9 | c.1822G>A p.D608N (on ENST00000262013 / NM_001130528.3; = p.D594N on NM_003971.6) | Missense Mutation (SNP) | VAF 12/220 reads (5%) | SIFT deleterious (0.04); PolyPhen benign (0.347); called by muse, mutect2
- SVIL | c.3422A>T p.D1141V (on ENST00000355867 / NM_021738.3; = p.D715V on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TLR7 | c.609G>C p.L203F | Missense Mutation (SNP) | VAF 46/195 reads (24%) | SIFT tolerated (0.08); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- TONSL | c.743T>A p.I248N | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.726); called by muse, mutect2, varscan2
- TTI1 | c.586G>A p.E196K | Missense Mutation (SNP) | VAF 189/425 reads (44%) | SIFT tolerated (0.37); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- TUT4 | c.3492C>G p.F1164L | Missense Mutation (SNP) | VAF 32/79 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- WDR59 | c.1054G>A p.E352K | Missense Mutation (SNP) | VAF 48/148 reads (32%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- ADAMTSL1 | c.654C>T p.V218= | Silent (SNP) | VAF 40/1540 reads (3%) | called by muse, mutect2
- ATG2A | c.4185C>T p.Y1395= | Silent (SNP) | VAF 13/17 reads (76%) | called by muse, mutect2, varscan2
- ATG2B | c.6057C>T p.H2019= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs770271550; called by muse, mutect2, varscan2
- ATP1A2 | c.2448C>T p.A816= | Silent (SNP) | VAF 29/177 reads (16%) | catalogued as rs769000078; called by muse, mutect2, varscan2
- BABAM2 | c.1125G>A p.E375= | Silent (SNP) | VAF 77/187 reads (41%) | called by muse, mutect2, varscan2
- CRACDL | c.2517C>T p.D839= | Silent (SNP) | VAF 15/40 reads (38%) | called by muse, mutect2, varscan2
- CSPP1 | c.3165A>G p.L1055= (on ENST00000676605; = p.L1014= on NM_024790.6) | Silent (SNP) | VAF 15/78 reads (19%) | catalogued as rs1014781544; called by muse, mutect2, varscan2
- FBXW10 | c.762C>T p.P254= | Silent (SNP) | VAF 57/155 reads (37%) | called by muse, mutect2, varscan2
- HSPG2 | c.2916G>A p.T972= | Silent (SNP) | VAF 11/32 reads (34%) | catalogued as rs1294706536; called by muse, mutect2, varscan2
- KCNMA1 | c.1962C>T p.I654= | Silent (SNP) | VAF 66/121 reads (55%) | called by muse, mutect2, varscan2
- MED25 | c.960C>T p.F320= | Silent (SNP) | VAF 20/85 reads (24%) | called by muse, mutect2, varscan2
- SPAG17 | c.3060C>T p.H1020= | Silent (SNP) | VAF 106/238 reads (45%) | catalogued as rs201385376, COSV60455766; called by muse, mutect2, varscan2
- ZNF516 | c.918C>T p.N306= | Silent (SNP) | VAF 12/29 reads (41%) | called by muse, mutect2, varscan2
- ZNF559 | c.657C>T p.V219= | Silent (SNP) | VAF 105/130 reads (81%) | catalogued as rs139671538; called by muse, mutect2, varscan2
- ZNF611 | c.156G>C p.V52= | Silent (SNP) | VAF 58/229 reads (25%) | called by muse, mutect2, varscan2
- ZNF865 | c.2487C>T p.F829= | Silent (SNP) | VAF 11/24 reads (46%) | catalogued as rs1484211056; called by muse, mutect2
- AC079781.4 | chr7:97928355 C>G | 5'Flank (SNP) | VAF 8/16 reads (50%) | called by muse, mutect2, varscan2
- CUL2 | c.-22-2870G>C | Intron (SNP) | VAF 63/119 reads (53%) | called by muse, mutect2, varscan2
- DST | c.4296+4573G>A | Intron (SNP) | VAF 76/180 reads (42%) | called by muse, mutect2, varscan2
- FAM86FP | n.232-597G>A | Intron (SNP) | VAF 32/62 reads (52%) | catalogued as rs759742168; called by muse, mutect2, varscan2
- MBD5 | c.2845+320G>A | Intron (SNP) | VAF 52/398 reads (13%) | called by muse, mutect2, varscan2
- NME7 | c.991-21123G>A | Intron (SNP) | VAF 34/175 reads (19%) | called by muse, mutect2, varscan2
- UBE4B | c.580+9C>T | Intron (SNP) | VAF 13/51 reads (25%) | catalogued as rs753962500; called by muse, mutect2, varscan2
